Somatic mutation profile of tumor specimen ALCH-B05T-TTP1-A (aliquot ALCH-B05T-TTP1-A-1-0-D-A680-36) from ALCHEMIST case ALCH-B05T, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Age at diagnosis: 39.4 years (14,407 days).
Specimen ALCH-B05T-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb1dc5ea-f686-476d-9775-9eb2154838e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B05T-NB1-A (Blood Derived Normal), aliquot ALCH-B05T-NB1-A-1-0-D-A680-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e85f4084-a739-475c-8cad-a97edc877b01

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Silent 2, Splice Site 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CORIN | c.2377C>T p.R793C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375618006; called by muse, mutect2
- ODAM | c.270G>T p.Q90H | Missense Mutation (SNP) | VAF 18/342 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as COSV101258049, COSV68573040; called by muse, mutect2
- ZNF99 | c.2466T>G p.C822W | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV68055493; called by muse, mutect2
- C12orf29 | c.265dup p.R89Kfs*3 | Frame Shift Ins (INS) | VAF 22/184 reads (12%) | called by mutect2, pindel
- CAND1 | c.2227A>T p.R743* | Nonsense Mutation (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- GINM1 | c.278-4_279delinsTTTTTT p.X93_splice | Splice Site (ONP) | VAF 8/50 reads (16%) | called by mutect2*, pindel
- LAS1L | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MAPK7 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 20/332 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- PTAR1 | c.712C>T p.H238Y | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TIGD2 | c.745T>C p.Y249H | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZFX | c.2309A>T p.H770L | Missense Mutation (SNP) | VAF 118/466 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KRTAP11-1 | c.189C>T p.P63= | Silent (SNP) | VAF 9/138 reads (7%) | called by muse, mutect2
- THSD7B | c.1872G>T p.G624= | Silent (SNP) | VAF 10/183 reads (5%) | called by muse, mutect2
